Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AALC, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AALC-01A (Primary Tumor).

Concerning

Summary pathology report

Left orchidectomy; nonseminoma (EC 90% YST 5%, SE 5%, scattered trophoblastic giant cells); diameter 3.5 cm; angio-invasion present; no invasion of rete testis present; tumor confined to testis.

Date of procurement (= date of orchidectomy):

ICD O-3
Carcinoma, embryonal NOS
9070/3
Site: @ Testis NOS
C62.9
7/5 3/5/14

pathologist

professor of pathology

Criteria	1/23/14	Yes	No

Source: NCI Genomic Data Commons file f6129e6e-fba5-44e3-83fa-8192b365aae4 (TCGA-2G-AALC-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).